Somatic mutation profile of tumor specimen TCGA-AB-2923-03A (aliquot TCGA-AB-2923-03A-01W-0745-08) from TCGA case TCGA-AB-2923, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.2 years (28,551 days).
Specimen TCGA-AB-2923-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd51d913-ebb1-4588-83a5-b2cad2a83c4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2923-11A (Solid Tissue Normal), aliquot TCGA-AB-2923-11A-01W-0745-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3629c842-3e7d-4012-bde3-20406817028d

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STRC | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs759718652, COSV70835060; called by mutect2, varscan2
- TMEM104 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as rs1324071389, COSV100120516, COSV59110512; called by muse, mutect2, varscan2
